Somatic mutation profile of tumor specimen 0DTUIN from CCDI case PBCJTZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.0 years (1,101 days).
Specimen 0DTUIN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85946808-397c-41b5-b73b-78039c0d94a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTUI0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22a6f7fa-72ea-4358-a2ab-86028b500d55

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A3 | c.868G>A p.E290K (on ENST00000545399 / NM_001256214.2; = p.E277K on NM_152296.5) | Missense Mutation (SNP) | VAF 44/868 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80356533, CM042304, COSV57486736; ClinVar: pathogenic; called by muse, mutect2
- ANKMY1 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 444/1388 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374902226; called by muse, mutect2, varscan2
- PLEKHG3 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 352/771 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1412366839, COSV55978004; called by muse, varscan2
- CATSPER2 | c.1391-1G>A p.X464_splice (on ENST00000321596 / NM_001282309.3; = p.X466_splice on NM_172095.4) | Splice Site (SNP) | VAF 36/1158 reads (3%) | called by muse, mutect2
- CIC | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 875/1909 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PTGER3 | c.1061T>C p.L354P | Missense Mutation (SNP) | VAF 182/1165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 28/1163 reads (2%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- CSMD3 | c.10194G>A p.T3398= (on ENST00000297405 / NM_001363185.1; = p.T3229= on NM_052900.3) | Silent (SNP) | VAF 278/1437 reads (19%) | catalogued as rs762493390; called by muse, mutect2, varscan2
- FOXRED2 | c.1773C>T p.T591= | Silent (SNP) | VAF 611/1362 reads (45%) | catalogued as rs1174861489, COSV99340928; called by muse, mutect2, varscan2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 28/1152 reads (2%) | catalogued as rs1267156464; called by muse, mutect2
- MUC19 | n.20664-51T>C | Intron (SNP) | VAF 40/410 reads (10%) | called by muse, mutect2
